Somatic mutation profile of tumor specimen 0DCXAT from CCDI case PBBNBU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 14.5 years (5,286 days).
Specimen 0DCXAT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2808410-9d81-4748-8ee2-c322551acc9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCXAB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b392d56a-c3a3-40e9-92b9-f8e052d4df22

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, Silent 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AZI2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 821/1996 reads (41%) | catalogued as rs747023944; called by muse, varscan2
- CHL1 | c.3554A>C p.Y1185S (on ENST00000397491 / NM_001253387.1; = p.Y1201S on NM_006614.4) | Missense Mutation (SNP) | VAF 536/1340 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56585456; called by muse, varscan2
- CTCF | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 266/782 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV50472487; called by muse, varscan2
- NRSN2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs765498315; called by muse, varscan2
- PRR23A | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 258/830 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.984); catalogued as rs1428729329; called by muse, varscan2
- COL6A2 | c.1637G>C p.G546A | Missense Mutation (SNP) | VAF 162/476 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- RFC2 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 314/786 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- ZNF736 | c.861T>G p.C287W | Missense Mutation (SNP) | VAF 188/424 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR8K3 | c.360C>T p.Y120= | Silent (SNP) | VAF 246/963 reads (26%) | catalogued as rs540217928, COSV100449783, COSV57131669; called by muse, varscan2
- ZNF462 | c.5346C>T p.I1782= | Silent (SNP) | VAF 89/415 reads (21%) | catalogued as rs376882323, COSV52947222; called by muse, varscan2
- CFAP52 | c.1575+75G>A | Intron (SNP) | VAF 44/112 reads (39%) | catalogued as rs994039125; called by muse, varscan2
- FAM153CP | n.491+68C>T | Intron (SNP) | VAF 187/436 reads (43%) | called by muse, varscan2
- NXPH2 | c.-86C>A | 5'UTR (SNP) | VAF 25/58 reads (43%) | called by muse, varscan2
- TPRA1 | c.671-60G>A | Intron (SNP) | VAF 44/84 reads (52%) | called by muse, varscan2
- ULK4 | c.541+25G>T | Intron (SNP) | VAF 215/454 reads (47%) | catalogued as rs769627440; called by muse, varscan2
